Somatic mutation profile of tumor specimen TCGA-4Z-AA7N-01A (aliquot TCGA-4Z-AA7N-01A-11D-A391-08) from TCGA case TCGA-4Z-AA7N, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 66.0 years (24,090 days).
Specimen TCGA-4Z-AA7N-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f059e00f-a0f6-4307-ac69-02efddec1757.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-4Z-AA7N-10A (Blood Derived Normal), aliquot TCGA-4Z-AA7N-10A-01D-A394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e6470cfc-86a2-41b7-94c9-964e4e756240

The open-access MAF lists 15 somatic variants for this specimen: 8 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 6, Missense Mutation 6, Nonsense Mutation 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CUBN | c.9538G>T p.D3180Y | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV64723995; called by muse, mutect2
- KERA | c.680G>A p.G227E | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT tolerated (0.91); PolyPhen benign (0.003); catalogued as rs1202916698, COSV57131500; called by muse, mutect2
- PDE8B | c.461G>C p.R154T | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV53743105; called by muse, mutect2
- PRSS54 | c.124G>T p.D42Y | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.374); catalogued as COSV54690930; called by mutect2, varscan2
- RFC4 | c.913C>G p.Q305E | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); catalogued as COSV99961159; called by muse, mutect2
- ZNF263 | c.949C>T p.Q317* | Nonsense Mutation (SNP) | VAF 12/176 reads (7%) | catalogued as COSV99526868; called by muse, mutect2
- ZNF280B | c.158C>T p.S53L | Missense Mutation (SNP) | VAF 6/130 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV64529466; called by muse, mutect2
- ELAVL3 | c.903G>A p.W301* | Nonsense Mutation (SNP) | VAF 5/76 reads (7%) | called by muse, mutect2
- CREB3 | c.546C>G p.V182= | Silent (SNP) | VAF 18/226 reads (8%) | catalogued as COSV59210620; called by muse, mutect2
- DLG1 | c.708C>T p.F236= | Silent (SNP) | VAF 5/100 reads (5%) | catalogued as COSV100015594, COSV58388772; called by muse, mutect2
- FLT1 | c.2580G>A p.V860= | Silent (SNP) | VAF 8/138 reads (6%) | catalogued as COSV56732783, COSV56737735, COSV99150562; called by muse, mutect2
- NMBR | c.114G>A p.T38= | Silent (SNP) | VAF 3/33 reads (9%) | catalogued as COSV99237217; called by muse, mutect2
- ST8SIA2 | c.111C>G p.G37= | Silent (SNP) | VAF 4/76 reads (5%) | catalogued as COSV99184417; called by muse, mutect2
- TP53BP2 | c.570G>A p.E190= (on ENST00000343537 / NM_001031685.3; = p.E61= on NM_005426.2) | Silent (SNP) | VAF 9/139 reads (6%) | catalogued as COSV59071740; called by muse, mutect2
- SLC3A2 | chr11:62853378 C>G | 5'Flank (SNP) | VAF 6/86 reads (7%) | called by muse, mutect2
